Somatic mutation profile of tumor specimen ASCProject_0026_T1_WES (aliquot ASCProject_0026_T1_WES_1) from CMI case ASCProject_0026, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 56.5 years (20,651 days).
Specimen ASCProject_0026_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 445b5497-02a8-409d-80a2-c59e75809016.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0026_BLOOD_Normal (Buffy Coat), aliquot ASCProject_0026_BLOOD_Normal_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60178a26-3cc9-4d91-905d-7a504d48e1c9

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 7, Frame Shift Del 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MTOR | c.4448G>A p.C1483Y | Missense Mutation (SNP) | VAF 8/61 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs786205165, CM1412980, CM153079, COSV63869079, COSV63869516; ClinVar: likely pathogenic; called by muse, mutect2
- PANK3 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 7/58 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs77612793; called by mutect2, varscan2
- CCSER1 | c.1964C>T p.T655M | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.437); catalogued as rs747739818; called by muse, mutect2, varscan2
- ERG | c.1066C>T p.R356W (on ENST00000398919 / NM_001243428.1; = p.R332W on NM_004449.4) | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750603713, COSV55731477; called by muse, mutect2, varscan2
- KANSL1 | c.598G>T p.D200Y | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs777713473; called by muse, varscan2
- L3MBTL3 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs758860319; called by muse, mutect2, varscan2
- LRRC14 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.788); catalogued as rs761785047, COSV52879105; called by muse, mutect2
- NR3C2 | c.476del p.T159Sfs*3 | Frame Shift Del (DEL) | VAF 26/145 reads (18%) | catalogued as COSV60991982; called by mutect2, pindel, varscan2
- PARD3 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs766247927, COSV60747447; called by muse, mutect2, varscan2
- PRAM1 | c.1909G>T p.G637C | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55313406; called by muse, mutect2, varscan2
- UGT2A1 | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs767856867, COSV54142254; called by muse, mutect2, varscan2
- CFAP65 | c.1379G>A p.C460Y | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- FMO1 | c.46G>C p.A16P | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- GPR137 | c.449T>A p.F150Y | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LAMC3 | c.1169C>T p.S390F | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2Z1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- PCDH19 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- PTPRA | c.2191C>T p.H731Y | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PXMP2 | c.491T>G p.F164C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RC3H2 | c.2087A>C p.D696A | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TMEM167B | c.113A>T p.K38M | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCAP31 | c.21A>T p.A7= | Silent (SNP) | VAF 37/111 reads (33%) | called by muse, mutect2, varscan2
- GPC4 | c.627C>G p.L209= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV63699163; called by muse, mutect2
- LGALS13 | c.282C>T p.Y94= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs376422089; called by muse, mutect2, varscan2
- NAGA | c.942A>T p.G314= | Silent (SNP) | VAF 27/170 reads (16%) | called by muse, mutect2, varscan2
- PSMB4 | c.105G>A p.A35= | Silent (SNP) | VAF 25/193 reads (13%) | catalogued as COSV51850799; called by muse, mutect2, varscan2
- SCPEP1 | c.165C>G p.L55= | Silent (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- ZNF701 | c.1596G>A p.*532= (on ENST00000301093; = p.*466= on NM_018260.3) | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV56528041; called by mutect2, varscan2
- RNF170 | c.*1715C>T | 3'UTR (SNP) | VAF 33/172 reads (19%) | catalogued as rs537465805; called by muse, mutect2, varscan2
- RNF217-AS1 | n.3543G>T | RNA (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
